TARGET case TARGET-15-SJMPAL041121 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1da25604-66d1-49de-89b6-b37b2489b041

Demographics
Sex at birth: male; Age at index: 6 years; Vital status: Alive.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 6.6 years (2,415 days); Year of diagnosis: 2015; Days to last follow up: 360 days.

Follow-up (1 entry)
- Days to follow up: 360 days; Event-free: no event (relapse, second malignancy or death) recorded through day 360; Year of follow up: 2016.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 43.1 ×10³/µL.

Biospecimens (2 samples)
- Samples TARGET-15-SJMPAL041121-09A.1, TARGET-15-SJMPAL041121-09A.2 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 360
- Protocol: Israel
- WBC at Diagnosis: 43.1
- Initial Therapy: ALL
- Karyotype: 46,XY,der(9)add(9)(p?) TLX3 split meaning t(5;14) confirmed by FISH
- WHO ALAL Classification: T/M
- WHO Dx: T/M
